Gene-level copy-number profile of tumor specimen TCGA-77-7140-01A from TCGA case TCGA-77-7140, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 69.3 years (25,303 days).
Specimen TCGA-77-7140-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.43e161fc-004b-4d99-9a68-e80d38f4f2c3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-77-7140-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/08db7f52-40b8-449a-b307-4c3285b14215

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 62; copy number 1: 4,753; copy number 2: 25,633; copy number 3: 14,837; copy number 4: 8,688; copy number 5: 2,950; copy number 6: 1,817; copy number 7: 766; copy number 8: 110; copy number 9: 75; copy number 10: 120; copy number 11: 4; copy number 19: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-77-7140-01A-41D-2041-01): tumor purity 0.78, ploidy 2.79, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 62 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:77,316,752–77,317,598, 1 gene: VDAC1P7.
- chr7:79,335,780–79,357,594, 3 genes: AC074024.1, RNU6-530P, AC004945.1.
- chr10:86,756,601–87,971,930, 46 genes (within-gene range 0–1): BMPR1A, RPAP2P1, RNU1-19P, MMRN2, AC025268.1, SNCG, ADIRF-AS1, ADIRF, AL136982.7, AGAP11, BMS1P3, AL136982.1, AL136982.6, AL136982.4, AL136982.2, FAM25A, AL136982.5, RNU6-529P, GLUD1, SHLD2, AL136982.3, RN7SL733P, NUTM2A-AS1, AL157893.2, AL157893.1, NUTM2A, LINC00863, NUTM2D, NPAP1P3, CTSLP1, FAM245A, AL355334.1, AL355334.2, MIR4678, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2.
- chr13:91,485,793–91,486,870, 1 gene: AL356118.1.
- chr14:32,149,176–32,882,830, 11 genes: AL161665.1, AL161665.2, RNU6-7, RNU6-8, AL136298.2, KIAA1143P1, AKAP6, AL136298.1, RN7SL660P, MTCO1P2, AL049781.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,074 genes in 49 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:193,457,422–194,198,708, 5 genes, copy number 5 (within-gene range 4–5): AL138778.1, AL136456.1, AL357793.1, AL357793.2, RPL23AP22.
- chr1:202,348,699–204,377,665, 69 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr1:219,685,427–220,360,183, 19 genes, copy number 5: SLC30A10, RNA5SP76, U3, EPRS1, BPNT1, IARS2, MIR215, MIR194-1, RPS15AP12, RAB3GAP2, MIR664A, SNORA36B, SNX2P1, KF455155.1, MORF4L1P1, AURKAP1, XRCC6P3, AL451081.2, AL451081.1.
- chr2:39,786,453–69,942,945, 481 genes, copy number 5 (broad region; genes not listed).
- chr2:80,572,681–83,657,842, 24 genes, copy number 5: AC008067.1, AC012355.1, ANKRD11P1, CHMP4AP1, LINC01815, RNA5SP99, AC013262.1, RN7SL201P, AC079896.1, LYARP1, RNU6-685P, Y_RNA, AC010105.1, RBX1P1, MTND4P25, MTND5P27, MTND6P7, MTCYBP7, AC098817.1, DHFRP3, AC138623.1, LINC01809, RPL37P10, RNU6-1312P.
- chr2:165,857,475–166,611,482, 9 genes, copy number 7 (within-gene range 4–7): TTC21B, TTC21B-AS1, SCN1A-AS1, SCN1A, Y_RNA, RN7SKP152, SCN9A, SCN7A, AC074101.1.
- chr2:176,611,437–181,694,900, 91 genes, copy number 6 (broad region; genes not listed).
- chr3:105,366,909–111,665,750, 80 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr3:111,732,497–118,810,836, 104 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr3:160,755,602–177,349,166, 189 genes, copy number 7–9 (within-gene range 4–9) (broad region; genes not listed).
- chr3:179,452,395–198,222,513, 438 genes, copy number 5–7 (broad region; genes not listed).
- chr4:43,133,867–43,598,844, 7 genes, copy number 9–19: AC111198.1, AC097451.1, AC098590.2, AC098590.1, LINC02383, AC114774.1, RN7SL691P.
- chr4:68,928,463–89,999,409, 374 genes, copy number 5 (broad region; genes not listed).
- chr5:28,213,359–43,886,628, 267 genes, copy number 5 (broad region; genes not listed).
- chr5:60,945,177–62,146,946, 17 genes, copy number 6 (within-gene range 1–6): NDUFAF2, AC008498.2, AC008498.1, SMIM15, SMIM15-AS1, LINC02057, ZSWIM6, AC122718.2, AC122718.1, RPL3P6, C5orf64, AC026746.1, RNU6-913P, C5orf64-AS1, AC026434.1, AC008877.1, RN7SKP157.
- chr7:15,611,212–17,940,501, 36 genes, copy number 5 (within-gene range 4–5): MEOX2, AC005550.2, LINC02587, AC005550.1, RPL36AP26, AC006041.2, AC006041.1, CRPPA, RPL36AP29, CRPPA-AS1, SOSTDC1, AC005014.3, LRRC72, AC005014.1, AC005014.2, ANKMY2, AC005014.4, BZW2, AC073333.1, TSPAN13, AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2, AHR, AC098592.1, AC073332.1, BRWD1P3, Metazoa_SRP, AC019117.3, SNORA63, AC019117.2, AC019117.1, AC006482.1, SNX13.
- chr7:36,734,004–36,841,373, 5 genes, copy number 5: AC007349.4, AC007349.1, AC007349.3, NPM1P18, AC007349.2.
- chr7:40,107,288–40,860,763, 7 genes, copy number 5 (within-gene range 4–5): AC006023.2, AC006023.1, MPLKIP, Y_RNA, SUGCT, THUMPD3P1, SUGCT-AS1.
- chr7:41,960,949–51,729,716, 168 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr7:65,235,790–66,811,464, 54 genes, copy number 6 (within-gene range 2–6): AC104073.2, AC104073.1, AC104073.4, AC104073.3, RSL24D1P3, AC092685.1, ZNF92, AC114501.3, AC114501.1, AC114501.2, AC104057.1, AC073107.1, INTS4P2, CCT6P1, SNORA22, SNORA15B-2, AC073107.2, GTF2IP5, RNU6-912P, AC093582.1, RNU6-973P, VKORC1L1, GUSB, AC073261.1, AC068533.2, AC068533.1, ASL, AC068533.4, CRCP, AC068533.3, TPST1, RNU6-313P, LINC00174, GTF2IP9, SKP1P1, AC008267.2, AC008267.4, AC008267.7, AC008267.5, AC008267.6, GS1-124K5.4, AC008267.1, AC008267.3, AC006001.3, AC006001.4, SAPCD2P3, AC006001.1, RPL35P5, KCTD7, AC027644.4, AC006001.2, RABGEF1, AC027644.3, AC027644.2.
- chr8:51,257,688–70,403,808, 287 genes, copy number 6–10 (within-gene range 2–10) (broad region; genes not listed).
- chr8:111,699,519–120,373,573, 66 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr9:92,676,943–113,759,419, 404 genes, copy number 5–8 (broad region; genes not listed).
- chr10:16,823,966–18,659,285, 26 genes, copy number 5 (within-gene range 2–5): CUBN, AC067747.1, TRDMT1, VIM-AS1, VIM, AL133415.1, ST8SIA6, ST8SIA6-AS1, Y_RNA, PRPF38AP2, HACD1, AC069542.2, STAM-AS1, STAM, AC069542.1, TMEM236, MRC1, MIR511, AC069023.1, SLC39A12, SLC39A12-AS1, CACNB2, AL390783.1, AL450384.2, AL450384.1, NSUN6.
- chr10:42,279,734–43,130,351, 27 genes, copy number 5 (within-gene range 2–5): PABPC1P8, BX322639.1, CCNYL2, AL391099.1, LINC00839, ZNF37BP, FXYD6P1, EIF3LP2, ZNF33B, AL022345.3, AL022345.1, AL022345.2, RNU6-1170P, AL022345.4, LINC01518, VN1R54P, CUBNP1, LINC02632, RSU1P1, DUXAP3, AL022344.1, BMS1, RNU6-885P, LINC02623, LINC01264, MIR5100, RET.
- chr10:45,615,500–45,727,231, 4 genes, copy number 11: ZFAND4, AGAP10P, FAM21FP, AL645998.1.
- chr10:73,168,119–73,697,881, 26 genes, copy number 5: FAM149B1, DNAJC9, Y_RNA, EIF4A2P2, AC016394.2, DNAJC9-AS1, MRPS16, DNAJC9-AS1, CFAP70, RNU6-833P, Y_RNA, ANXA7, AL512656.1, RPL26P6, MSS51, PPP3CB, PPP3CB-AS1, USP54, RNU6-883P, RPS26P41, AC073389.1, AC073389.3, MYOZ1, SYNPO2L, AC073389.2, AGAP5.
- chr11:45,847,118–47,330,031, 50 genes, copy number 5: CRY2, MAPK8IP1, AC068385.1, C11orf94, PEX16, LARGE2, PHF21A, AC024475.1, AC024475.3, AC024475.2, LINC02710, AC116021.1, LINC02489, CREB3L1, DGKZ, MIR4688, MDK, CHRM4, AMBRA1, AC024293.1, MIR3160-1, MIR3160-2, AC127035.1, HARBI1, ATG13, ARHGAP1, ZNF408, F2, CKAP5, MIR5582, AC115088.1, SNORD67, LRP4-AS1, LRP4, AC021573.1, C11orf49, AC103792.1, AC090589.2, ARFGAP2, AC090589.3, PACSIN3, MIR6745, AC090589.1, DDB2, AC018410.1, ACP2, NR1H3, MADD, MADD-AS1, AC090582.1.
- chr11:102,942,995–103,479,863, 7 genes, copy number 5 (within-gene range 3–5): MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1.
- chr12:66,767–13,982,002, 495 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr12:24,566,964–25,885,855, 34 genes, copy number 5: LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, MIR4302, AC019209.1.
- chr15:32,536,047–38,226,897, 107 genes, copy number 5 (broad region; genes not listed).
- chr15:76,931,738–77,420,144, 11 genes, copy number 6: RCN2, RN7SL278P, KRT8P23, PSTPIP1, TSPAN3, AC090181.1, AC090181.3, AC090181.2, PEAK1, AC087465.1, AC060773.1.
- chr15:85,255,369–101,933,350, 382 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr16:49,442,910–50,235,310, 26 genes, copy number 5–9: AC007861.1, AC007861.2, LINC02179, ZNF423, ADAM3B, MRPS21P7, AC027348.2, MRPS21P8, AC027348.1, AC007603.2, AC007603.1, RPL34P29, AC007603.3, CNEP1R1, AC007610.1, AC007610.3, Metazoa_SRP, ACTG1P16, HEATR3, AC007610.4, RNY4P3, AC007610.2, AC007610.5, RPL10P14, SNORA70, TENT4B.
- chr17:63,454,993–64,956,546, 81 genes, copy number 6 (broad region; genes not listed).
- chr18:14,361,434–30,414,073, 184 genes, copy number 5–7 (broad region; genes not listed).
- chr20:87,250–916,334, 26 genes, copy number 5 (within-gene range 4–5): DEFB125, DEFB126, DEFB127, DEFB128, DEFB129, DEFB132, AL034548.1, C20orf96, ZCCHC3, AL034548.2, NRSN2-AS1, SOX12, NRSN2, TRIB3, RBCK1, TBC1D20, Y_RNA, CSNK2A1, TCF15, SRXN1, AL121758.1, SCRT2, SLC52A3, FAM110A, RPS10P5, ANGPT4.
- chr20:4,780,023–25,452,628, 364 genes, copy number 6 (broad region; genes not listed).
- chr21:21,933,315–22,154,299, 5 genes, copy number 7: AP000472.1, LINC01687, LINC00308, AP000705.2, AP000705.1.

Autosomal genes at a single copy (total copy number 1): 4,438. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
